Somatic mutation profile of tumor specimen TCGA-50-8457-01A (aliquot TCGA-50-8457-01A-11D-2323-08) from TCGA case TCGA-50-8457, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 63.1 years (23,055 days).
Specimen TCGA-50-8457-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5ce9296-fb6b-46c7-96f0-147fb37ff33f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-8457-10A (Blood Derived Normal), aliquot TCGA-50-8457-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e0d20ca-4628-4bd1-b8de-db0f29507693

The open-access MAF lists 59 somatic variants for this specimen: 47 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 11, Nonsense Mutation 7, Frame Shift Ins 2, Splice Site 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AACS | c.1184C>G p.P395R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55540933, COSV99907884; called by muse, mutect2, varscan2
- ABCC11 | c.3699-1G>T p.X1233_splice | Splice Site (SNP) | VAF 44/131 reads (34%) | catalogued as COSV62321799; called by muse, mutect2, varscan2
- APC | c.1627-1G>T p.X543_splice | Splice Site (SNP) | VAF 17/51 reads (33%) | catalogued as COSV99966614, COSV99971587; called by muse, mutect2
- ARHGAP5 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV100565142, COSV61539242; called by muse, mutect2, varscan2
- ASTN1 | c.2207C>G p.S736C | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV99920989; called by muse, mutect2, varscan2
- ATP13A1 | c.3248A>G p.K1083R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99179147; called by muse, mutect2, varscan2
- ATP7A | c.1064C>G p.S355* | Nonsense Mutation (SNP) | VAF 9/281 reads (3%) | catalogued as COSV100430547; called by muse, mutect2
- ATP7A | c.1862C>A p.T621K | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV100430549; called by muse, mutect2
- ATR | c.1027A>T p.K343* | Nonsense Mutation (SNP) | VAF 28/87 reads (32%) | catalogued as COSV100637929; called by muse, mutect2, varscan2
- CLIP2 | c.884C>G p.P295R | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99791268; called by muse, mutect2, varscan2
- CYB5R4 | c.512A>G p.D171G | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100859647; called by muse, varscan2
- DCST1 | c.716T>C p.M239T | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1180318099, COSV99792921; called by muse, mutect2
- ERN1 | c.2529G>T p.Q843H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1008186868, COSV101458417; called by muse, mutect2, varscan2
- FYCO1 | c.2398C>T p.R800W | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs200646936, COSV99945422; called by muse, mutect2, varscan2
- GAA | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.331); catalogued as COSV100163065; called by muse, mutect2, varscan2
- GBF1 | c.4501G>C p.D1501H (on ENST00000369983 / NM_001377137.1; = p.D1500H on NM_004193.3) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100890396; called by muse, mutect2, varscan2
- HEPH | c.3098A>T p.E1033V (on ENST00000343002; = p.E766V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100294537; called by muse, mutect2, varscan2
- HS3ST4 | c.984G>A p.W328* | Nonsense Mutation (SNP) | VAF 47/251 reads (19%) | catalogued as COSV100500719, COSV58802705; called by muse, mutect2, varscan2
- IL17RD | c.1794G>C p.E598D | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV99576858, COSV99577093; called by muse, mutect2, varscan2
- ITIH6 | c.1472G>T p.W491L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99513078; called by muse, mutect2, varscan2
- KIAA1109 | c.6049A>T p.R2017* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as COSV99151118; called by muse, mutect2, varscan2
- MAX | c.137T>C p.L46S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52415235, COSV99408404; called by muse, mutect2, varscan2
- NF1 | c.6185G>C p.C2062S (on ENST00000358273 / NM_001042492.3; = p.C2041S on NM_000267.3) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as rs1555534668, COSV100646463, COSV62192879; ClinVar: uncertain significance; called by muse, mutect2
- NLRP8 | c.2393G>A p.C798Y | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1257360671, COSV99404995; called by muse, mutect2, varscan2
- NUDT10 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs781913106; called by muse, mutect2
- OPRL1 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs750611641, COSV61091444; called by muse, mutect2, varscan2
- OR10P1 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV100548154; called by muse, mutect2, varscan2
- OR13C2 | c.599T>A p.L200H | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.684); catalogued as COSV101604864, COSV73377743; called by muse, mutect2, varscan2
- PHLDB2 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as rs201915760, COSV67312595; called by muse, mutect2, varscan2
- PLXNB3 | c.2140C>A p.L714M | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV100737252; called by muse, mutect2
- PRKCD | c.1546G>T p.A516S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100387771; called by muse, mutect2, varscan2
- PSG1 | c.418T>A p.F140I | Missense Mutation (SNP) | VAF 25/337 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV99739395; called by muse, mutect2
- SALL4 | c.2971C>T p.Q991* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV99409349; called by muse, mutect2, varscan2
- SFMBT2 | c.1088T>A p.L363H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100738732; called by muse, mutect2, varscan2
- SLC23A1 | c.1124C>A p.T375K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100811887, COSV100811932; called by muse, mutect2, varscan2
- TDRD3 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV99540011; called by muse, mutect2, varscan2
- TENM2 | c.7283G>A p.R2428H (on ENST00000518659 / NM_001122679.2; = p.R2189H on NM_001080428.3) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs367921349; called by muse, mutect2, varscan2
- THAP8 | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV99495692; called by muse, mutect2, varscan2
- TMEM63C | c.2291C>A p.T764N | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.148); catalogued as COSV100029315; called by muse, mutect2, varscan2
- TTBK2 | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV99141245; called by muse, mutect2, varscan2
- TUBGCP3 | c.2179C>T p.L727F | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99996678; called by muse, mutect2, varscan2
- YARS2 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100256353; called by muse, mutect2, varscan2
- ZNF91 | c.149C>G p.A50G | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV100322465, COSV56090810; called by muse, mutect2, varscan2
- CMTR2 | c.770_772del p.C257_E258delins* | Nonsense Mutation (DEL) | VAF 23/77 reads (30%) | called by mutect2, pindel, varscan2
- SETDB1 | c.652dup p.L218Pfs*18 | Frame Shift Ins (INS) | VAF 23/115 reads (20%) | called by mutect2, pindel, varscan2
- TRAPPC11 | c.1080dup p.K361Efs*9 | Frame Shift Ins (INS) | VAF 21/94 reads (22%) | called by mutect2, pindel, varscan2
- YBX2 | c.653_658del p.Q218_R219del | In Frame Del (DEL) | VAF 30/127 reads (24%) | called by mutect2, pindel, varscan2
- ALAS2 | c.75G>T p.V25= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100238144; called by muse, mutect2
- BMP2K | c.3225T>C p.H1075= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV99784976; called by muse, mutect2, varscan2
- COX4I2 | c.207G>A p.K69= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV101064205; called by muse, mutect2
- EPPK1 | c.954C>T p.L318= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs371861329, COSV73260933; called by muse, mutect2, varscan2
- LZTR1 | c.711G>T p.R237= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV99301523; called by muse, mutect2, varscan2
- RASGRF2 | c.1908G>T p.V636= | Silent (SNP) | VAF 56/212 reads (26%) | catalogued as COSV99428859; called by muse, mutect2, varscan2
- SH2D3C | c.2163G>A p.K721= (on ENST00000314830 / NM_170600.3; = p.K564= on NM_005489.4) | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV100136648; called by muse, mutect2, varscan2
- TAAR2 | c.660T>C p.T220= (on ENST00000367931 / NM_001033080.1; = p.T175= on NM_014626.3) | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as rs763667490, COSV51579214, COSV99255589; called by muse, mutect2, varscan2
- UBB | c.480G>T p.L160= | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as COSV100141605; called by muse, mutect2
- VN1R4 | c.615A>C p.I205= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs142023427; called by muse, varscan2
- VWF | c.1635G>A p.R545= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV99778539; called by muse, mutect2, varscan2
- ODF2 | c.124-300G>A | Intron (SNP) | VAF 11/45 reads (24%) | catalogued as rs564746923, COSV63549084; called by muse, mutect2, varscan2
